Surgical pathology report (de-identified scan), TCGA case TCGA-P4-A5E7, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  MD Anderson Cancer Center, specimen TCGA-P4-A5E7-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID:

Normal Sample ID:

Pathology Report

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

COMMENT

This addendum report is issued to comment on the type of papillary renal cell carcinoma, as it was not mentioned in the original report. There is no other change in diagnosis.

After review of the H&E slides, this tumor is designated as type 2 papillary renal cell carcinoma.

DIAGNOSIS

(A) LEFT PARTIAL NEPHRECTOMY:

PAPILLARY RENAL CELL CARCINOMA, FUHRMAN'S NUCLEAR GRADE 3.

TUMOR CONFINED TO KIDNEY.

TUMOR MEASURES 4.5 CM IN MAXIMUM DIMENSION.

Margins of resection free of tumor.

(B) LEFT PARTIAL NEPHRECTOMY II:

Renal parenchyma with focal glomerulosclerosis, no tumor present.

(See comment)

(C) ADRENAL BIOPSY:

Adrenal cortical tissue. (See comment)

COMMENT

The specimen designated left partial nephrectomy (specimen B), consists of a fragment of renal parenchyma with focal glomerulosclerosis. Multiple additional deeper sections were examined.

The specimen designated adrenal biopsy (specimen C), consists of a fragment of adrenal cortical tissue. No metastatic carcinoma is identified. Correlation with the clinical findings is suggested.

GROSS DESCRIPTION

(A) LEFT PARTIAL NEPHRECTOMY - DEEP MARGIN - INK FROZEN SECTION INKED

MARGIN - A partial nephrectomy specimen with attached perinephric fat (9.0 x 8.0 x 2.0 cm overall). The portion of kidney is approximately 5.0 x 5.0 x 2.0 cm and is marked with blue surgical ink along part of the parenchymal resection margin.

A 4.5 x 4.0 x 1.9 cm friable orange-brown and focally hemorrhagic tumor mass is present within the kidney parenchyma. The tumor is less than 0.2 cm from the nearest parenchymal margin. No gross extension into perinephric fat is noted. The surrounding renal parenchyma is light tan and unremarkable.

INK CODE: Black - parenchymal resection margin; blue - surgically marked parenchymal margin.

SECTION CODE: A1, A2, frozen sections of parenchymal margin; A3-A6, tumor with margin; A7-A9, tumor with surrounding adipose and normal kidney; A10, tumor with blue surgical ink; A11-A16, additional tumor section.

*FS/DX: REPRESENTATIVE MARGIN FREE OF TUMOR.

(B) LEFT PARTIAL NEPHRECTOMY #2 - A 0.9 x 0.5 x 0.4 cm portion of renal parenchyma. The apparent cortical surface displays a 0.3 x 0.3 tan area of vague nodularity. The apparent parenchymal margin is tan and unremarkable. The cut surface does not show grossly invasive tumor.

ICD-0-3
Carcinoma, papillary renal
cell 8260/3
Site: ② Kidney NOS
C64.9
JW 11/10/13

JW 12/31/12
JW 12/20/12

[page 2 of 2]
Department of Pathology

Tissue Source Site (TSS) #:

Patholgy Accession No:

Patient ID:

Normal Sample ID:

Tumor Sample ID:

INK CODE: Blue-apparent cortical surface, orange-apparent parenchymal margin.

SECTION CODE: B, entire left partial nephrectomy.

(C) ADRENAL BIOPSY, RULE OUT METASTASIS - A single portion of soft, yellow tissue (1.2 x 0.5 x 0.3 cm) is submitted entirely for frozen section in C.

*FS/DX: ADRENAL CORTICAL TISSUE, NO METASTATIC CARCINOMA.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-Y7343

"Some tests reported here may have been developed and performance characteristics determined by

. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Source: NCI Genomic Data Commons file 016d474a-b6f5-40ec-a9d4-f9345f170965 (TCGA-P4-A5E7.FFA18E29-2CC3-48F3-A7F2-88FC092E5606.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).